TCGA case TCGA-09-1664 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3438c018-9856-4628-ae59-7d365713647f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 37 years; Vital status: Dead; Days to death: 2,279 days (6.2 years).

Diagnoses (1)
1. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 37.6 years (13,739 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G1; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 15 days; Days to treatment end: 139 days; Number of cycles: 6; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 2,279.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-1664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.7.
  Slide TCGA-09-1664-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 2; Percent stromal cells: 8.
  Slide TCGA-09-1664-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 18; Percent necrosis: 2; Percent stromal cells: 5.
- Sample TCGA-09-1664-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form: Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,279 days; disease-specific survival: event status not recorded, 2,279 days; disease-free interval: no event (censored), 2,279 days; progression-free interval: no event (censored), 2,279 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-09-1664-01A-01D-0577-01): tumor purity 0.91, ploidy 1.9, whole-genome doublings 0.
